Somatic mutation profile of tumor specimen MP2PRT-PASNMS-TMP1-A (aliquot MP2PRT-PASNMS-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASNMS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,262 days).
Specimen MP2PRT-PASNMS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d12a5317-2b25-4a6b-9d4c-0897a581c56b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNMS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNMS-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffae84c2-d41d-4a93-9a9d-fca921d6267b

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRRAP | c.2947G>A p.A983T | Missense Mutation (SNP) | VAF 143/396 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs972402682, COSV100722685, COSV62841564; called by muse, mutect2, varscan2
- CHL1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTC26 | c.276A>T p.E92D | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- C20orf194 | c.2727C>T p.L909= | Silent (SNP) | VAF 18/546 reads (3%) | called by muse, mutect2
- KCNB2 | c.666C>T p.D222= | Silent (SNP) | VAF 144/427 reads (34%) | catalogued as rs768533276, COSV101578973; called by muse, mutect2, varscan2
- MUC5B | c.10557C>T p.T3519= | Silent (SNP) | VAF 272/744 reads (37%) | catalogued as rs779444776, COSV71595668; called by muse, varscan2
